Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A2J4, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A2J4-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

1CD-0-3

dedifferentiated liposarcoma
8858/3

Site: Retroperitoneum C48.0

hw 7/24/11

....

Clinical Diagnosis & History:

Left sided abdominal mass found after experiencing fatigue and weight loss.

Specimens Submitted:

- 1: SP: Spleen
- 2: SP: Radical resection of left retroperitoneal sarcoma and left kidney, adrenal and left colon
- 3: SP: End of sigmoid colon

DIAGNOSIS:

- 1) SPLEEN, SPLENECTOMY:
- SPLEEN WITH SCATTERED GRANULOMAS/LIPOGRANULOMAS.
- ACID-FAST AND GMS STAINS ARE NEGATIVE FOR MICROORGANISMS.
- 2) SOFT TISSUE, LEFT KIDNEY ADRENAL AND LEFT COLON, RESECTION:
- DEDIFFERENTIATED LIPOSARCOMA; MOST OF THE TUMOR CONSISTS OF WELL DIFFERENTIATED SCLEROSING, INFLAMMATORY, AND LIPOMA-LIKE WELL DIFFERENTIATED LIPOSARCOMA, BUT HYPERCELLULAR AREAS WITH ASSOCIATED MITOTIC ACTIVITY AND NECROSIS (E.G. SECTIONS 15 AND 19) ARE ALSO PRESENT.
- TUMOR MEASURES 22 CM GREATEST DIMENSION, INVOLVES FIBROADIPOSE TISSUE, SHOWS ABOUT 30% NECROSIS (GROSS ESTIMATE), AND COMES WITHIN 0.1 CM OF INKED SOFT TISSUE MARGIN.
- KIDNEY, ADRENAL GLAND AND COLON WITH NO SIGNIFICANT ABNORMALITY.
- IMMUNOSTAINS FOR CDR4 AND MDM2 ARE POSITIVE.
- 3) COLON, END OF SIGMOID, RESECTION:
- SEGMENT OF COLON, NO TUMOR SEEN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
--------	---------------	---------

** Continued on next page **

[page 2 of 3]
AFB

Gross Description:

1). The specimen is received fresh, labeled "spleen" and consists of a segment of spleen weighing 190 grams and measuring 10.0 x 6.0 x 4.5 cm. There is an attached portion of hilar fat measuring 8.0 x 4.3 x 4.0 cm. Serial sections reveal no gross lesion. Representative sections are submitted.

Summary of sections:

S spleen

SH spleen with hilar fat

2). The specimen is received fresh and is labeled "radical resection of left retroperitoneal sarcoma with left kidney, adrenal and left colon" and consists of a kidney with attached ureter and vessels, adrenal gland, a portion of left colon, and a soft tissue mass. The portion of colon measures 35 x 4 cm and appears unremarkable. The attached kidney measures 9 x 7 x 6 cm and appears unremarkable with a well-defined corticomedullary junction. The attached adrenal gland measures 5 x 1.5 x 0.4 cm and appears unremarkable. The colon, kidney, and adrenal gland are not involved by tumor. In the attached mesentery there is an encapsulated soft tissue mass which measures 22 x 21 x 15 cm. The mass appears to be encapsulated and involves adjacent fibroadipose tissue. The mass does not involve adjacent structures. The external surface of the mass is inked black. Serial sectioning reveals a white tan, firm, slightly gelatinous cut surface with a central cavity of necrosis and hemorrhage spanning a diameter of 10.0 cm. The tumor is approximately 30% necrotic. The remainder of the soft tissue mass is fairly homogeneous. A photograph has been taken. A portion of the tumor is submitted for TPS. Representatively submitted.

Summary of sections:

PCM - proximal colonic margin

DCM - distal colonic margin

UVM - ureteral and vessel margins

NC - normal colon

NA - normal adrenal

NK - normal kidney

T- tumor

3.) The specimen is received in formalin and is labeled "End of sigmoid colon" and consists of a 2.5 cm in length by 1.6 cm in diameter portion of sigmoid colon with attached focally hemorrhagic pericolic fat. The serosal surface is glistening, smooth tan-white and is inked in black. Bowel shows glistening, tan-pink plicated mucosa and a slightly thickened muscularis, up to 0.6 cm in maximum thickness. Representative sections are submitted.

** Continued on next page **

[page 3 of 3]
Summary of sections:

M margins
P -- pericolic fat
RS -- representative sections

Summary of Sections:

Part 1: SP: Spleen

Block	Sect.	Site	PCs
2		S	2
2		SH	2

Part 2: SP: Radical resection of left retroperitoneal sarcoma and left kidney, adrenal and left colon

Block	Sect.	Site	PCs
1		dcm	1
1		na	1
1		nc	1
1		nk	1
1		pcm	1
27		t	27
1		uvm	1

Part 3: SP: End of sigmoid colon

Block	Sect.	Site	PCs
2		M	2
1		P	1
2		RS	2

** End of Report **

Source: NCI Genomic Data Commons file 4cbb4d59-efcf-4804-a9a1-178615a16b7a (TCGA-DX-A2J4.51103A9A-33A6-414F-8D17-6DA63DEF6BC3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).